Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V6, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V6-01A (Primary Tumor).

[page 1 of 2]
Neck
Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

year old with Non-Hodgkins lymphoma status post R chop with bilateral thyroid nodules and papillary thyroid cancer.

Specimens Submitted:

1: Total thyroidectomy

DIAGNOSIS:

1. Total thyroidectomy:

Tumor Type:

Papillary carcinoma, tall cell variant

Mitotic Activity:

Not identified

≥ 50% tall cell features per TSS / h

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

ICD-O-3

Tumor Size:

Greatest diameter is 1.8 cm.

Carcinoma, papillary, tall cell

8344/3

Tumor Encapsulation:

None identified

Site: thyroid, NOS

Blood Vessel Invasion:

Not identified

C73.9 5-2-12
12

Extrathyroid Extension:

Invades perithyroid fibroadipose tissue

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Numerous foci of papillary microcarcinoma are present in the right lobe (0.1 to 0.8cm) and left lobe (0.1 to 0.8cm).

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "total thyroidectomy" and consists of a thyroid weighing 21 g. The right lobe measures 5.5 x 2.5 x 1 cm, the left lobe measures 5 x 3 x 1 cm and the isthmus measures 1.5 x 1 x 1 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals an ill-defined, tan, firm nodule in the left lobe measuring 1.8 x 1.2 x 1 cm and a well-circumscribed, tan nodule in the right lobe measuring 0.8 x 0.7 x 0.7 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for . The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

NL- nodule left lobe
NR- nodule right lobe
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
6	LL	6
4	NL	4
1	NR	1
11	RL	11

Source: NCI Genomic Data Commons file 8dd99afe-f4f6-4dfa-b790-6e5f532eaad3 (TCGA-DJ-A3V6.C6F0A1E3-BFC0-4458-8FB0-824FE6DB3086.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).